Somatic mutation profile of tumor specimen C3N-02088-04 (aliquot CPT0118290006) from CPTAC case C3N-02088, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 60.3 years (22,039 days).
Specimen C3N-02088-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 143ffebd-8a1a-47fc-9abb-89075c9290ce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02088-31 (Blood Derived Normal), aliquot CPT0119510002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd6fbdeb-29cc-4fa6-a102-f89c8c7cae48

The open-access MAF lists 96 somatic variants for this specimen: 62 protein-altering or splice-affecting, 21 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 21, Intron 7, Nonsense Mutation 4, 3'UTR 2, Frame Shift Del 2, In Frame Del 1, RNA 1, 5'UTR 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2236_2250del p.E746_A750del | In Frame Del (DEL) | VAF 129/470 reads (27%) | hotspot (GDC flag); catalogued as rs727504233, COSV51765066, COSV51849442; ClinVar: drug response; called by mutect2, pindel, varscan2
- ADAMTS16 | c.2152G>A p.E718K | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.656); catalogued as COSV57004608; called by muse, mutect2
- ADAMTS7 | c.4813G>A p.E1605K | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs1320383322, COSV66307270; called by muse, mutect2, varscan2
- ALOX15 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 20/294 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99541515; called by muse, mutect2
- ARHGAP31 | c.865G>C p.E289Q | Missense Mutation (SNP) | VAF 27/357 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.375); catalogued as COSV51792594; called by muse, mutect2
- C11orf71 | c.235G>C p.D79H | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.865); catalogued as COSV100348338, COSV57784357; called by muse, mutect2
- CENPQ | c.207G>C p.K69N | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.133); catalogued as rs973705801, COSV100225611; called by muse, mutect2
- DARS2 | c.1187A>G p.N396S | Missense Mutation (SNP) | VAF 35/215 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0.01); catalogued as rs766404473; called by muse, mutect2, varscan2
- DNAH17 | c.1688A>T p.Y563F | Missense Mutation (SNP) | VAF 31/170 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.068); catalogued as COSV67760991; called by muse, mutect2, varscan2
- DNAH9 | c.8893C>T p.R2965C | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as rs193137604, COSV52335061; called by muse, mutect2, varscan2
- IGFN1 | c.2050C>T p.R684W (on ENST00000295591 / NM_001367841.1; = p.R3141W on NM_001164586.2) | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs369913949; called by muse, mutect2, varscan2
- MANEA | c.1165G>A p.A389T | Missense Mutation (SNP) | VAF 17/194 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs772610838, COSV100721443, COSV100721465; called by muse, mutect2
- MATK | c.293G>A p.G98E (on ENST00000310132 / NM_139355.3; = p.G99E on NM_002378.4) | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1472091129, COSV59553880; called by muse, mutect2
- MSRB3 | c.122G>T p.C41F | Missense Mutation (SNP) | VAF 25/566 reads (4%) | SIFT tolerated (0.73); PolyPhen benign (0.083); catalogued as COSV57590969; called by muse, mutect2
- NRXN1 | c.3721C>T p.R1241C | Missense Mutation (SNP) | VAF 24/248 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60485335; called by muse, mutect2
- NRXN2 | c.3457C>G p.P1153A | Missense Mutation (SNP) | VAF 28/360 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as COSV55447163; called by muse, mutect2
- OR4K1 | c.733A>G p.T245A | Missense Mutation (SNP) | VAF 12/175 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.174); catalogued as COSV53461107, COSV53461444; called by muse, mutect2
- PCDH17 | c.1541C>G p.S514W | Missense Mutation (SNP) | VAF 19/215 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV64971600; called by muse, mutect2
- PSMD4 | c.299G>A p.R100Q | Missense Mutation (SNP) | VAF 53/228 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1398034825; called by muse, mutect2, varscan2
- REG3A | c.47C>A p.S16Y | Missense Mutation (SNP) | VAF 32/177 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.685); catalogued as COSV59408953; called by muse, mutect2, varscan2
- RGL2 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 6/86 reads (7%) | catalogued as COSV101442493; called by muse, mutect2
- RIC1 | c.3874A>G p.I1292V | Missense Mutation (SNP) | VAF 24/320 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773889558; called by muse, mutect2
- RNF213 | c.14427C>G p.I4809M | Missense Mutation (SNP) | VAF 18/432 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.792); catalogued as COSV100301204; called by muse, mutect2
- SUZ12 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV59497789; called by muse, mutect2
- THNSL2 | c.1172C>T p.P391L | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1445306523; called by muse, mutect2
- ADGB | c.1438A>G p.K480E | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- ADGRA3 | c.2959G>A p.E987K | Missense Mutation (SNP) | VAF 26/362 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2
- ANKDD1B | c.526C>T p.Q176* | Nonsense Mutation (SNP) | VAF 12/153 reads (8%) | called by muse, mutect2
- ARG2 | c.467C>T p.S156L | Missense Mutation (SNP) | VAF 22/229 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); called by muse, mutect2
- ATR | c.4877A>G p.Y1626C | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- CCDC102A | c.572_579del p.P191Qfs*19 | Frame Shift Del (DEL) | VAF 6/48 reads (13%) | called by mutect2, pindel, varscan2
- CPSF6 | c.1405C>T p.L469F | Missense Mutation (SNP) | VAF 16/506 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- FAM71B | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2
- FLG2 | c.3679G>C p.E1227Q | Missense Mutation (SNP) | VAF 22/228 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.011); called by muse, mutect2
- GCN1 | c.3977T>C p.L1326P | Missense Mutation (SNP) | VAF 13/292 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GNAI1 | c.433G>C p.E145Q | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- GPR21 | c.784T>C p.Y262H | Missense Mutation (SNP) | VAF 29/260 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HMX3 | c.899C>A p.A300E | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- IER3IP1 | c.232C>T p.L78F | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); called by muse, mutect2
- KIR3DL2 | c.281G>T p.R94I | Missense Mutation (SNP) | VAF 48/418 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- MINAR1 | c.82C>G p.Q28E | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- MYBPC3 | c.1677G>C p.K559N | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.044); called by muse, varscan2
- NBEA | c.4462C>A p.Q1488K | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); called by muse, mutect2
- NBPF12 | c.2488G>A p.E830K | Missense Mutation (SNP) | VAF 29/391 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- NSUN2 | c.388_389del p.N130Ffs*21 | Frame Shift Del (DEL) | VAF 28/242 reads (12%) | called by mutect2, pindel, varscan2
- OR6C70 | c.609G>A p.M203I | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); called by muse, mutect2
- PCDHGA10 | c.1402A>T p.N468Y | Missense Mutation (SNP) | VAF 61/236 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PHC3 | c.1795G>A p.E599K (on ENST00000494943 / NM_001308116.2; = p.E611K on NM_024947.4) | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- PIK3CB | c.2686C>T p.R896* | Nonsense Mutation (SNP) | VAF 22/371 reads (6%) | called by muse, mutect2
- PYGB | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- SELENOI | c.437G>C p.R146T | Missense Mutation (SNP) | VAF 22/373 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.434); called by muse, mutect2
- SETD1B | c.3574G>T p.E1192* | Nonsense Mutation (SNP) | VAF 26/291 reads (9%) | called by muse, mutect2
- SETD4 | c.826G>T p.D276Y | Missense Mutation (SNP) | VAF 30/297 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SI | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2
- SLC38A11 | c.193A>G p.I65V | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- ST8SIA3 | c.681C>A p.D227E | Missense Mutation (SNP) | VAF 8/190 reads (4%) | PolyPhen possibly damaging (0.545); called by muse, mutect2
- TEX15 | c.7555G>C p.V2519L (on ENST00000256246; = p.V2902L on NM_001350162.2) | Missense Mutation (SNP) | VAF 7/204 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2
- TTC21A | c.400G>C p.D134H | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2
- UNC5CL | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.441); called by muse, mutect2
- VAT1 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 18/327 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.06); called by muse, mutect2
- Z83844.2 | c.919G>T p.A307S | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- ZNF536 | c.1875C>A p.N625K | Missense Mutation (SNP) | VAF 15/388 reads (4%) | SIFT tolerated (0.83); PolyPhen benign (0.01); called by muse, mutect2
- ANKRD34A | c.1218G>A p.R406= | Silent (SNP) | VAF 14/59 reads (24%) | called by muse, mutect2, varscan2
- ATP10D | c.2127A>G p.A709= | Silent (SNP) | VAF 13/118 reads (11%) | called by muse, mutect2
- BTNL3 | c.105C>T p.D35= | Silent (SNP) | VAF 28/246 reads (11%) | catalogued as rs183021703; called by muse, mutect2
- COL12A1 | c.6900G>A p.E2300= | Silent (SNP) | VAF 19/214 reads (9%) | catalogued as rs1194108575; called by muse, mutect2
- CPA1 | c.930G>A p.Q310= | Silent (SNP) | VAF 23/220 reads (10%) | catalogued as COSV99163391; called by muse, mutect2, varscan2
- CSMD1 | c.1920G>A p.A640= (on ENST00000520002; = p.A639= on NM_033225.6) | Silent (SNP) | VAF 24/288 reads (8%) | catalogued as rs369380015; called by muse, mutect2
- DUSP16 | c.1908C>A p.I636= | Silent (SNP) | VAF 13/217 reads (6%) | called by muse, mutect2
- EIF4G1 | c.1866C>T p.F622= (on ENST00000346169 / NM_198241.3; = p.F426= on NM_004953.5) | Silent (SNP) | VAF 42/457 reads (9%) | called by muse, mutect2
- FBXO4 | c.378G>A p.K126= | Silent (SNP) | VAF 22/166 reads (13%) | catalogued as rs774914020, COSV55854423; called by muse, mutect2, varscan2
- FOCAD | c.1377C>G p.L459= | Silent (SNP) | VAF 35/280 reads (13%) | called by muse, mutect2, varscan2
- GARS1 | c.649C>T p.L217= | Silent (SNP) | VAF 17/400 reads (4%) | called by muse, mutect2
- HDLBP | c.3252G>T p.V1084= | Silent (SNP) | VAF 26/208 reads (13%) | catalogued as COSV100191766; called by muse, mutect2, varscan2
- MYBPC3 | c.1701G>A p.E567= | Silent (SNP) | VAF 28/198 reads (14%) | catalogued as CD043685; called by muse, varscan2
- MYBPC3 | c.1560G>A p.E520= | Silent (SNP) | VAF 30/144 reads (21%) | called by muse, mutect2, varscan2
- NEB | c.3090G>T p.L1030= | Silent (SNP) | VAF 12/218 reads (6%) | called by muse, mutect2
- PCDHB8 | c.1638G>A p.A546= | Silent (SNP) | VAF 76/1774 reads (4%) | catalogued as COSV50754693; called by muse, mutect2
- PTK2 | c.261C>G p.L87= | Silent (SNP) | VAF 12/179 reads (7%) | catalogued as COSV61784078; called by muse, mutect2
- REG3A | c.48C>A p.S16= | Silent (SNP) | VAF 32/177 reads (18%) | catalogued as COSV59408204; called by muse, mutect2, varscan2
- SLC15A3 | c.168C>G p.L56= | Silent (SNP) | VAF 7/166 reads (4%) | called by muse, mutect2
- SPIC | c.333C>A p.L111= | Silent (SNP) | VAF 18/59 reads (31%) | called by muse, mutect2, varscan2
- ZNF214 | c.93C>T p.V31= | Silent (SNP) | VAF 7/116 reads (6%) | catalogued as COSV53480498; called by muse, mutect2
- CNOT3 | c.2037+82A>C | Intron (SNP) | VAF 5/54 reads (9%) | called by muse, mutect2
- CSGALNACT1 | c.*951C>G | 3'UTR (SNP) | VAF 11/325 reads (3%) | called by muse, mutect2
- CTRC | c.*80T>C | 3'UTR (SNP) | VAF 54/289 reads (19%) | called by muse, mutect2, varscan2
- GARS1 | c.735+23C>T | Intron (SNP) | VAF 16/416 reads (4%) | called by muse, mutect2
- IL36B | c.261+832T>C | Intron (SNP) | VAF 35/160 reads (22%) | catalogued as rs771790331; called by muse, mutect2, varscan2
- MED13L | c.5175+14A>T | Intron (SNP) | VAF 28/153 reads (18%) | called by muse, mutect2, varscan2
- MED15 | c.157-282C>T | Intron (SNP) | VAF 10/220 reads (5%) | called by muse, mutect2
- MIR125B1 | n.67C>T | RNA (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- MIR5195 | chr14:106851266 C>T | 5'Flank (SNP) | VAF 37/415 reads (9%) | catalogued as rs545752688; called by muse, mutect2
- MYH11 | c.4578+26C>T | Intron (SNP) | VAF 52/507 reads (10%) | catalogued as rs369034509; called by muse, mutect2, varscan2
- NEMF | c.-11C>A | 5'UTR (SNP) | VAF 15/202 reads (7%) | catalogued as COSV53591366; called by muse, mutect2
- PLXDC1 | chr17:39061156 C>G | 3'Flank (SNP) | VAF 10/92 reads (11%) | catalogued as rs1157317859; called by muse, mutect2
- TMEM87A | c.1063-630T>C | Intron (SNP) | VAF 8/113 reads (7%) | called by muse, mutect2
